Somatic mutation profile of tumor specimen HCM-CSHL-0434-C24-06A (aliquot HCM-CSHL-0434-C24-06A-11D-A78U-36) from HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cb06780-e221-457b-a59a-e4a8fc5b9969.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0434-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0434-C24-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20eace5a-24ec-489c-9fa5-b23e14e5265c

The open-access MAF lists 61 somatic variants for this specimen: 37 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Nonsense Mutation 2, Splice Site 2, Intron 2, 3'UTR 2, 5'Flank 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 47/409 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 80/753 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASCC3 | c.4729G>A p.A1577T | Missense Mutation (SNP) | VAF 25/432 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.312); catalogued as rs187359221; called by muse, mutect2
- CFAP46 | c.7202G>A p.R2401Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375364632, COSV99583945; called by muse, mutect2
- CFL1 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 31/443 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV57380536; called by muse, mutect2
- DUSP7 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs879043778; called by muse, mutect2
- ESX1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs782576955; called by muse, mutect2, varscan2
- FARP2 | c.288+2T>C p.X96_splice | Splice Site (SNP) | VAF 12/172 reads (7%) | catalogued as rs1166151853; called by muse, mutect2
- FLG | c.4387G>A p.G1463R | Missense Mutation (SNP) | VAF 28/642 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1341902735; called by muse, mutect2
- GLP2R | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575133662, COSV52324255; called by muse, mutect2
- KLHL42 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 62/640 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as rs374664683; called by muse, mutect2
- LTBP1 | c.2878G>T p.E960* (on ENST00000404816 / NM_206943.4; = p.E634* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 28/217 reads (13%) | catalogued as COSV100617209, COSV63195429; called by muse, mutect2, varscan2
- MAGEB4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs770408937, COSV66775187; called by muse, mutect2, varscan2
- PLXNA2 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as rs778037020; called by muse, mutect2
- SIPA1L2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs368264412; called by muse, mutect2
- SKOR1 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV58244084; called by muse, mutect2
- SLC24A3 | c.788A>C p.Q263P | Missense Mutation (SNP) | VAF 32/550 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.112); catalogued as COSV100043446; called by muse, mutect2
- TMPRSS6 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 54/640 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1270960721, COSV60976662; called by muse, mutect2
- TUB | c.124C>T p.R42C (on ENST00000299506 / NM_177972.3; = p.R97C on NM_003320.4) | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs772509519; called by muse, mutect2
- TUBA3C | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs372020555, COSV67139306; called by muse, mutect2, varscan2
- VPS13D | c.8530G>T p.D2844Y | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1425394183; called by muse, mutect2
- ZBED9 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.953); catalogued as rs185476387, COSV71729796; called by muse, mutect2
- ZFHX2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1457340621; called by muse, mutect2
- ARID3C | c.213G>T p.E71D | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2
- DACT1 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GON4L | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF1 | c.2938G>C p.V980L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LIFR | c.2319G>A p.M773I | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- PPHLN1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- PRPF6 | c.2029-1G>A p.X677_splice | Splice Site (SNP) | VAF 40/476 reads (8%) | called by muse, mutect2
- PZP | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- RHO | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 12/362 reads (3%) | called by muse, mutect2
- TMEM8B | c.1102C>A p.R368S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UBR5 | c.5366G>A p.S1789N | Missense Mutation (SNP) | VAF 29/476 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- WFDC1 | c.478T>C p.Y160H | Missense Mutation (SNP) | VAF 50/428 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF26 | c.1118G>A p.G373D | Missense Mutation (SNP) | VAF 41/400 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- ZSWIM5 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 22/321 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- A2M | c.66C>T p.D22= | Silent (SNP) | VAF 12/379 reads (3%) | catalogued as rs1397674410; called by muse, mutect2
- ARMC4 | c.1668C>T p.A556= | Silent (SNP) | VAF 49/501 reads (10%) | catalogued as rs761407359; called by muse, mutect2
- COL6A3 | c.1641G>A p.E547= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- DLGAP2 | c.933G>A p.T311= | Silent (SNP) | VAF 35/472 reads (7%) | catalogued as rs746806848; called by muse, mutect2
- FAM53C | c.222G>C p.L74= | Silent (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
- FBXO28 | c.858C>T p.R286= | Silent (SNP) | VAF 22/368 reads (6%) | called by muse, mutect2
- HECA | c.1620C>T p.L540= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as rs1380380608, COSV62768603; called by muse, mutect2
- HOXB3 | c.127C>T p.L43= | Silent (SNP) | VAF 47/349 reads (13%) | called by muse, mutect2, varscan2
- HSPG2 | c.7662C>T p.N2554= | Silent (SNP) | VAF 46/532 reads (9%) | called by muse, mutect2
- NRG1 | c.1593C>T p.Y531= (on ENST00000405005 / NM_013964.5; = p.Y536= on NM_013956.5) | Silent (SNP) | VAF 36/494 reads (7%) | catalogued as rs576124928, COSV55153115; called by muse, mutect2
- OCA2 | c.1221C>T p.F407= | Silent (SNP) | VAF 32/353 reads (9%) | catalogued as rs370349105; called by muse, mutect2
- ORAI2 | c.489C>T p.A163= | Silent (SNP) | VAF 40/534 reads (7%) | catalogued as rs769632596; called by muse, mutect2
- SH3TC2 | c.2964G>A p.L988= | Silent (SNP) | VAF 24/448 reads (5%) | catalogued as rs1189055074, COSV60466406; called by muse, mutect2
- SLC26A4 | c.474C>T p.D158= | Silent (SNP) | VAF 64/405 reads (16%) | catalogued as COSV55915305; called by muse, mutect2, varscan2
- SLC9A9 | c.1404C>T p.L468= | Silent (SNP) | VAF 23/303 reads (8%) | catalogued as rs576013614, COSV100339003, COSV57235318; called by muse, mutect2
- TP73 | c.1863C>T p.A621= | Silent (SNP) | VAF 21/230 reads (9%) | called by muse, mutect2
- ZNF862 | c.58T>C p.L20= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- C19orf12 | chr19:29699652 T>C | 3'Flank (SNP) | VAF 51/448 reads (11%) | called by muse, mutect2, varscan2
- EMP1 | c.*1781C>A | 3'UTR (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- MTHFD2L | chr4:74157926 T>C | 5'Flank (SNP) | VAF 23/346 reads (7%) | catalogued as rs1299716458; called by muse, mutect2
- POTEM | c.811-1175T>C | Intron (SNP) | VAF 31/631 reads (5%) | called by muse, mutect2
- REPIN1 | c.-92C>G | 5'UTR (SNP) | VAF 30/397 reads (8%) | catalogued as rs1367020694; called by muse, mutect2
- SLC26A3 | c.1677+28dup | Intron (INS) | VAF 54/382 reads (14%) | catalogued as rs771040356; called by mutect2, pindel*, varscan2
- SLC39A9 | c.*3077C>T | 3'UTR (SNP) | VAF 8/153 reads (5%) | called by muse, mutect2
